Gene-level copy-number profile of tumor specimen TCGA-B6-A0RV-01A from TCGA case TCGA-B6-A0RV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 42.5 years (15,507 days).
Specimen TCGA-B6-A0RV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.671267f1-3fef-4709-8df2-97b8cb9cf052.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0RV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39c94c97-0d02-46bf-86e4-24521865138d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,804; copy number 2: 44,856; copy number 3: 4,987; copy number 4: 765; copy number 5: 230; copy number 6: 5; copy number 10: 8; copy number 11: 84; copy number 12: 72; copy number 17: 2; copy number 23: 5; copy number 25: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0RV-01A-11D-A087-01): tumor purity 0.46, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 407 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:983,181–1,543,043, 19 genes, copy number 5: CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK.
- chr7:4,642,248–6,900,623, 82 genes, copy number 5 (broad region; genes not listed).
- chr7:12,726,152–13,751,920, 4 genes, copy number 5 (within-gene range 1–5): AC011287.1, RN7SKP228, RBMX2P4, AC011287.2.
- chr7:13,871,856–14,071,380, 4 genes, copy number 6: AC005019.1, ETV1, Y_RNA, RPL6P21.
- chr7:14,190,795–14,192,157, 1 gene, copy number 6: EEF1A1P26.
- chr7:19,112,474–21,514,822, 34 genes, copy number 5: AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183.
- chr7:21,900,899–23,832,513, 43 genes, copy number 5 (within-gene range 3–5): CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3.
- chr7:28,953,358–30,595,286, 48 genes, copy number 5 (within-gene range 3–5): TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4, AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3, WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3.
- chr8:34,228,439–34,346,731, 1 gene, copy number 23 (within-gene range 1–23): AC090993.1.
- chr8:34,322,992–38,468,834, 76 genes, copy number 12–23 (broad region; genes not listed).
- chr8:40,104,169–40,172,612, 4 genes, copy number 10: AC087518.1, LINC02866, TCIM, AC022733.1.
- chr11:81,175,201–82,718,299, 7 genes, copy number 10–25 (within-gene range 2–25): AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr17:59,106,598–61,413,280, 84 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,383. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
